Somatic mutation profile of tumor specimen TCGA-EE-A3J5-06A (aliquot TCGA-EE-A3J5-06A-11D-A20D-08) from TCGA case TCGA-EE-A3J5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.1 years (26,693 days).
Specimen TCGA-EE-A3J5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e93b4e7-0da7-4252-8161-9f76a02c19f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3J5-10A (Blood Derived Normal), aliquot TCGA-EE-A3J5-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a7390dd-f069-4c6a-8802-a80f09662663

The open-access MAF lists 2,584 somatic variants for this specimen: 1,723 protein-altering or splice-affecting, 791 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,541, Silent 791, Nonsense Mutation 101, Splice Site 31, RNA 28, Intron 24, Splice Region 20, Frame Shift Del 18, 5'UTR 7, Translation Start Site 4, 3'UTR 4, 3'Flank 4.

Variants (750 of 2,584; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372307320, CM050967; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 59/174 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52354600; called by muse, mutect2, varscan2
- CHRNA4 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121909580, CM950259, COSV64718594; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs727502827, COSV56018342; ClinVar: likely pathogenic; called by muse, mutect2
- COL6A2 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs387906610, CM099128, COSV52430808; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ERCC6 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as rs376526037; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNB1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518621, COSV65565954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ5 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663556; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5609G>A p.R1870Q (on ENST00000358273 / NM_001042492.3; = p.R1849Q on NM_000267.3) | Missense Mutation (SNP) | VAF 21/35 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs786202112, CM1411401, CS000055, CS1311534, CS1311535, COSV62210316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5609+1G>A p.X1870_splice (on ENST00000358273 / NM_001042492.3; = p.X1849_splice on NM_000267.3) | Splice Site (SNP) | VAF 22/36 reads (61%) | catalogued as rs1131691117, CS000879, CS072258, CS992457, COSV62194068, COSV62200690, COSV62224640; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGIF1 | c.425C>T p.S142F (on ENST00000330513 / NM_001374396.1; = p.S162F on NM_003244.4) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs121909069, CM001355, COSV57909962; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 28/47 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2ML1 | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.043); catalogued as COSV55300315; called by muse, varscan2
- AAAS | c.1568C>A p.P523Q | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV52934786; called by muse, mutect2, varscan2
- ABCA3 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV57061657; called by muse, mutect2, varscan2
- ABCA4 | c.2686A>T p.K896* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as CM1311060, COSV64679622; called by muse, mutect2, varscan2
- ABCA5 | c.4279C>T p.Q1427* | Nonsense Mutation (SNP) | VAF 74/160 reads (46%) | catalogued as COSV67019739; called by muse, mutect2, varscan2
- ABCB11 | c.3529G>A p.G1177R | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55603307; called by muse, mutect2, varscan2
- ABCC11 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1009209470, COSV62326504; called by muse, mutect2, varscan2
- ABCC5 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 89/128 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV55597752; called by muse, mutect2, varscan2
- ABHD3 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as rs776445992, COSV56679025; called by muse, mutect2, varscan2
- AC011455.2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55502222; called by muse, mutect2, varscan2
- AC068580.4 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1252953375, COSV52590088, COSV52590749; called by muse, mutect2, varscan2
- ACAN | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV61371497; called by muse, mutect2, varscan2
- ACAN | c.5135G>A p.G1712E | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs760776040, COSV61358864; called by muse, mutect2, varscan2
- ACHE | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53822573; called by muse, mutect2, varscan2
- ACOX3 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62714124; called by muse, varscan2
- ACP6 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV65078173; called by muse, mutect2
- ACSM3 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV56844741, COSV56847622; called by muse, mutect2, varscan2
- ACSM5 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV59375700; called by muse, mutect2, varscan2
- ACTB | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.104); catalogued as COSV59322119; called by muse, mutect2, varscan2
- ADAM19 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57441370; called by muse, mutect2, varscan2
- ADAM19 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57438574, COSV57441392; called by muse, mutect2, varscan2
- ADAM22 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55993223; called by muse, mutect2, varscan2
- ADAM23 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as rs775680717, COSV52227947, COSV52228939; called by muse, mutect2, varscan2
- ADAM29 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63667993, COSV63669340; called by muse, mutect2, varscan2
- ADAM29 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs1051260494, COSV63669346; called by muse, mutect2, varscan2
- ADAMTS13 | c.1788G>A p.A596= | Splice Region (SNP) | VAF 68/107 reads (64%) | catalogued as rs782132022, COSV63023622; called by muse, mutect2, varscan2
- ADAMTS20 | c.4027G>A p.D1343N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs374908169, COSV67130441; called by muse, mutect2, varscan2
- ADAMTS20 | c.3119G>A p.G1040E | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67139155, COSV99061796; called by muse, mutect2, varscan2
- ADAMTS20 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs780153600, COSV67137622; called by muse, mutect2, varscan2
- ADAMTS4 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs570236275, COSV63490368; called by muse, mutect2, varscan2
- ADAMTS5 | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV53183608, COSV53186644; called by muse, mutect2, varscan2
- ADAMTS6 | c.2160A>T p.E720D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV66866077; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4742C>T p.S1581F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs1372936621, COSV65879409; called by muse, mutect2, varscan2
- ADAMTSL3 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.112); catalogued as COSV54474205; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.719); catalogued as COSV55009212; called by muse, mutect2, varscan2
- ADARB1 | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62349282; called by muse, mutect2, varscan2
- ADCK1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 159/306 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); catalogued as COSV53087368; called by muse, mutect2, varscan2
- ADCY8 | c.1641G>A p.G547= | Splice Region (SNP) | VAF 58/227 reads (26%) | catalogued as COSV53916065; called by muse, mutect2, varscan2
- ADD3 | c.198C>T p.A66= | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as rs756834111, COSV53326854; called by muse, mutect2, varscan2
- ADGRB1 | c.3884C>T p.P1295L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV60095115; called by muse, mutect2, varscan2
- ADGRB3 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV65426007; called by muse, mutect2, varscan2
- ADGRB3 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 147/435 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369405391, COSV65394023; called by muse, mutect2, varscan2
- ADGRD1 | c.2384A>G p.N795S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55460643; called by muse, mutect2, varscan2
- ADGRE1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV51676040; called by muse, mutect2, varscan2
- ADGRF4 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 44/118 reads (37%) | catalogued as COSV51958848; called by muse, mutect2, varscan2
- ADGRF5 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV51930512, COSV51930891; called by muse, mutect2, varscan2
- ADGRL2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752679138, COSV54649550; called by muse, mutect2, varscan2
- ADGRL2 | c.2573C>T p.S858F (on ENST00000370717 / NM_001366005.1; = p.S845F on NM_012302.4) | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV54650682; called by muse, mutect2, varscan2
- ADGRL3 | c.2855G>A p.G952E (on ENST00000506720 / NM_001322402.2; = p.G884E on NM_015236.6) | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72232266; called by muse, mutect2, varscan2
- ADGRV1 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs761612567, COSV67988588; called by muse, mutect2, varscan2
- ADGRV1 | c.6431G>A p.G2144E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751354925, COSV67994121, COSV67996346; called by muse, mutect2, varscan2
- ADH1B | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1420645522, COSV59299373; called by muse, mutect2, varscan2
- ADH4 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372708357; called by muse, mutect2, varscan2
- ADIG | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100972558; called by muse, mutect2, varscan2
- ADIG | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64893716; called by muse, mutect2, varscan2
- ADIRF | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs750609216; called by muse, mutect2, varscan2
- ADRA1A | c.1191G>A p.W397* | Nonsense Mutation (SNP) | VAF 43/163 reads (26%) | catalogued as COSV52376712; called by muse, mutect2, varscan2
- AFF3 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57841553; called by muse, mutect2, varscan2
- AFMID | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as rs767731459, COSV56961182, COSV56961624; called by muse, mutect2, varscan2
- AGAP1 | c.1156-1G>A p.X386_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as rs895663158, COSV58341713; called by muse, mutect2, varscan2
- AGBL1 | c.2576G>A p.G859E | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV66877601; called by muse, mutect2, varscan2
- AGGF1 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57229361, COSV57231630; called by muse, mutect2, varscan2
- AGGF1 | c.1164T>G p.S388R | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV57231639; called by muse, mutect2, varscan2
- AGGF1 | c.2078T>A p.F693Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100462022; called by muse, mutect2, varscan2
- AGTR2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT tolerated (0.73); PolyPhen benign (0.039); catalogued as rs1556673873, COSV64157210; called by muse, mutect2, varscan2
- AHNAK2 | c.10081C>T p.P3361S | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.359); catalogued as COSV60933927; called by muse, mutect2, varscan2
- AK2 | c.431G>A p.R144H (on ENST00000354858; = p.R186H on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs754485826, COSV61470625; called by muse, varscan2
- AKAP3 | c.459A>T p.K153N | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV57421839; called by muse, mutect2, varscan2
- AKAP9 | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs772799572, COSV62360062; called by muse, mutect2, varscan2
- AKNAD1 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.822); catalogued as rs978217485, COSV62204966; called by muse, mutect2, varscan2
- AKR1D1 | c.261+1G>A p.X87_splice | Splice Site (SNP) | VAF 9/16 reads (56%) | catalogued as rs201988060, COSV99653169; called by muse, varscan2
- ALB | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV55742933; called by muse, mutect2, varscan2
- ALDH1L1 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs367736275; called by muse, mutect2, varscan2
- ALDH3B2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1178685549, COSV62429749; called by muse, mutect2, varscan2
- ALK | c.2804G>T p.G935V | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66593978; called by muse, mutect2, varscan2
- ALLC | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as COSV52998884; called by muse, mutect2, varscan2
- ALOX15 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV53401387; called by muse, mutect2, varscan2
- ALPK2 | c.4881G>A p.M1627I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64493213; called by muse, mutect2, varscan2
- ALPK3 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV51941773; called by muse, mutect2, varscan2
- AMBN | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59828455; called by muse, mutect2, varscan2
- AMBRA1 | c.3304C>T p.Q1102* (on ENST00000458649 / NM_001367468.1; = p.Q1012* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV54064095; called by muse, mutect2, varscan2
- ANGPT1 | c.1206G>C p.R402S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.28); catalogued as COSV52460309; called by muse, mutect2, varscan2
- ANGPT1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433501; called by muse, mutect2, varscan2
- ANGPT4 | c.1202G>T p.S401I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV67923225; called by muse, mutect2, varscan2
- ANGPT4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs749527768, COSV67923229; called by muse, mutect2, varscan2
- ANK1 | c.5350G>A p.E1784K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1184429661, COSV55898974; called by muse, mutect2, varscan2
- ANK2 | c.10045C>T p.P3349S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52143759; called by muse, mutect2, varscan2
- ANKAR | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV55619444; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51861099; called by muse, mutect2, varscan2
- ANKRD12 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV50858318; called by muse, mutect2, varscan2
- ANKRD30A | c.685G>T p.V229F (on ENST00000611781; = p.V173F on NM_052997.2) | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs767706646, COSV64624051; called by muse, mutect2, varscan2
- ANKRD30A | c.1510C>T p.Q504* (on ENST00000611781; = p.Q448* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV64624061; called by muse, mutect2, varscan2
- ANKRD30A | c.2779-1G>A p.X927_splice (on ENST00000611781; = p.X871_splice on NM_052997.2) | Splice Site (SNP) | VAF 30/85 reads (35%) | catalogued as COSV64624068; called by muse, mutect2, varscan2
- ANKRD36B | c.1126T>G p.L376V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV51538367; called by muse, mutect2, varscan2
- ANKS1A | c.3260C>T p.S1087F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV64465344; called by muse, mutect2, varscan2
- ANKZF1 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 42/126 reads (33%) | catalogued as rs1000301786, COSV55479656; called by muse, mutect2, varscan2
- ANO4 | c.2746C>T p.R916* (on ENST00000392977 / NM_001286615.2; = p.R881* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as rs778663996, COSV54617991; called by muse, mutect2, varscan2
- ANO5 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61091337; called by muse, mutect2, varscan2
- ANTXR1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV58019953; called by muse, mutect2, varscan2
- ANXA6 | c.1624T>G p.S542A | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV62908809; called by muse, mutect2
- AOAH | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51739585, COSV51745458; called by muse, mutect2, varscan2
- AOC3 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 111/305 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as COSV53829456; called by muse, mutect2, varscan2
- AP2B1 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV52003431; called by muse, mutect2, varscan2
- AP3B2 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs374158382; called by muse, mutect2, varscan2
- APC | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57390594; called by muse, mutect2, varscan2
- APOB | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs267599185, COSV51928488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBR | c.3025C>T p.R1009C (on ENST00000431282; = p.R1018C on NM_018690.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs528190355, COSV60489033; called by muse, mutect2, varscan2
- APOC2 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV52991090, COSV99377030; called by muse, mutect2, varscan2
- APOL5 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV50766948; called by muse, mutect2, varscan2
- APPL2 | c.1460-1G>A p.X487_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV51595165; called by muse, mutect2, varscan2
- ARF4 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV57716142; called by muse, mutect2, varscan2
- ARGFX | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | catalogued as rs267599565, COSV57682562; called by muse, mutect2, varscan2
- ARHGAP12 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs369851721; called by muse, mutect2, varscan2
- ARHGAP22 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV51010707; called by muse, mutect2, varscan2
- ARHGAP22 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.295); catalogued as rs1205639622, COSV51011354; called by muse, mutect2, varscan2
- ARHGAP26 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs182566788, COSV50831527; called by muse, mutect2, varscan2
- ARHGAP27 | c.1639-1G>A p.X547_splice (on ENST00000428638 / NM_001282290.1; = p.X206_splice on NM_199282.3) | Splice Site (SNP) | VAF 38/148 reads (26%) | catalogued as COSV65359041; called by muse, mutect2, varscan2
- ARHGAP28 | c.2087G>A p.G696E (on ENST00000383472 / NM_001366230.1; = p.G537E on NM_001010000.3) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58655441; called by muse, mutect2, varscan2
- ARHGAP31 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs1232621924, COSV51796827; called by muse, mutect2
- ARHGAP32 | c.2450C>T p.S817F (on ENST00000310343 / NM_001378025.1; = p.S468F on NM_014715.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV59843278; called by muse, mutect2, varscan2
- ARHGAP4 | c.2069A>C p.Q690P | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV61687176; called by muse, mutect2, varscan2
- ARHGAP44 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52404812; called by muse, varscan2
- ARHGEF12 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV63102858, COSV63107870; called by muse, mutect2, varscan2
- ARHGEF40 | c.1837-1G>A p.X613_splice | Splice Site (SNP) | VAF 63/140 reads (45%) | catalogued as rs11620774, COSV100070474; called by muse, mutect2, varscan2
- ARID3C | c.298T>C p.Y100H | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66698536; called by muse, mutect2, varscan2
- ARMC4 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV59456008; called by muse, mutect2, varscan2
- ARPC5 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 44/118 reads (37%) | catalogued as COSV54172830; called by muse, mutect2, varscan2
- ARPP21 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV51810739; called by muse, mutect2, varscan2
- ARR3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV52105597; called by muse, mutect2, varscan2
- ARSI | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV60818704; called by muse, mutect2, varscan2
- ART1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs577558078, COSV51707858; called by muse, mutect2, varscan2
- ASH1L | c.7003G>A p.E2335K (on ENST00000368346 / NM_001366177.2; = p.E2330K on NM_018489.3) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.332); catalogued as COSV64215063; called by muse, mutect2, varscan2
- ASIC1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV57320755; called by muse, mutect2, varscan2
- ASXL3 | c.3050C>T p.S1017F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52480980; called by muse, mutect2, varscan2
- ATF4 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as rs1184116702; called by muse, mutect2, varscan2
- ATF6B | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV64352889; called by muse, mutect2, varscan2
- ATF7IP2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771575139, COSV61094146; called by muse, mutect2, varscan2
- ATP13A2 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs778562581, COSV58700278; called by muse, mutect2, varscan2
- ATP13A4 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 120/177 reads (68%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as rs1224524332, COSV55070096, COSV55070206; called by muse, mutect2, varscan2
- ATP1A2 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 122/387 reads (32%) | catalogued as COSV63405682, COSV63406420; called by muse, mutect2, varscan2
- ATP1A2 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63406427; called by muse, mutect2, varscan2
- ATP2B4 | c.1459T>G p.Y487D | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV58185469; called by muse, mutect2, varscan2
- ATP4A | c.2117C>G p.P706R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52872735; called by muse, mutect2, varscan2
- ATP5MC2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV58602463; called by muse, mutect2, varscan2
- ATP6V1E2 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV60576827; called by muse, mutect2, varscan2
- ATP8A1 | c.2908G>A p.G970R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100046953, COSV52551083; called by muse, mutect2, varscan2
- ATP8A1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV52531272; called by muse, mutect2, varscan2
- ATP9B | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779876736; called by muse, mutect2, varscan2
- ATXN2 | c.2017T>C p.W673R (on ENST00000550104; = p.W513R on NM_002973.4) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs1266072561, COSV66486504; called by muse, mutect2, varscan2
- AXDND1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs192778181, COSV62648232; called by muse, mutect2, varscan2
- B4GALNT2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV55928834; called by muse, mutect2, varscan2
- B4GALNT3 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV56759277; called by muse, mutect2, varscan2
- BARX2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV55652827; called by muse, mutect2, varscan2
- BBS5 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV54754837; called by muse, mutect2, varscan2
- BCAN | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV61260225; called by muse, mutect2, varscan2
- BCL9L | c.4112C>T p.P1371L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs753922655, COSV52688634; called by muse, mutect2, varscan2
- BCO1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV50728197; called by muse, mutect2, varscan2
- BCR | c.3275C>T p.S1092F | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100006700; called by muse, mutect2, varscan2
- BCR | c.3766C>T p.P1256S | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.241); catalogued as COSV59937006; called by muse, mutect2, varscan2
- BHMT | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as COSV57156178; called by muse, mutect2, varscan2
- BICC1 | c.1766T>C p.L589P | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54067764; called by muse, mutect2, varscan2
- BICD1 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV55690176; called by muse, mutect2, varscan2
- BLOC1S5 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as COSV55243435; called by muse, mutect2, varscan2
- BMPER | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51831874; called by muse, mutect2, varscan2
- BNC1 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 41/144 reads (28%) | catalogued as COSV61759508; called by muse, mutect2, varscan2
- BNC1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1351578318, COSV61759511; called by muse, mutect2, varscan2
- BPIFB4 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs753941963, COSV64951254; called by muse, mutect2, varscan2
- BPIFC | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV55916631; called by muse, mutect2, varscan2
- BRD2 | c.47A>T p.N16I | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.396); catalogued as COSV66374849; called by muse, mutect2, varscan2
- BRD8 | c.1988C>T p.P663L (on ENST00000254900 / NM_139199.2; = p.P736L on NM_006696.4) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50177107; called by muse, mutect2, varscan2
- BRDT | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as rs776201694, COSV62868239; called by muse, mutect2, varscan2
- BRINP2 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64181091; called by muse, mutect2, varscan2
- BRINP2 | c.1638G>A p.W546* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV64181095; called by muse, mutect2, varscan2
- BTBD11 | c.2542G>A p.E848K (on ENST00000280758 / NM_001018072.2; = p.E385K on NM_001017523.2) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1255877123, COSV55040723; called by muse, mutect2, varscan2
- BTBD16 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV53267784; called by muse, mutect2, varscan2
- BTC | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs782722907, COSV67548207; called by muse, mutect2, varscan2
- BTG4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63637300; called by muse, mutect2, varscan2
- C10orf120 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV61492912; called by muse, mutect2, varscan2
- C1orf105 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV62962607; called by muse, mutect2, varscan2
- C20orf194 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.453); catalogued as COSV52704873; called by muse, mutect2, varscan2
- C3orf20 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53790461; called by muse, mutect2, varscan2
- C3orf22 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 121/296 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); catalogued as COSV59073430; called by muse, mutect2, varscan2
- C3orf56 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750530723, COSV67756588; called by muse, mutect2, varscan2
- C6 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138105385, COSV54706828, COSV54706891; called by muse, mutect2, varscan2
- C8A | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs773423532, COSV63486032; called by muse, varscan2
- CABIN1 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 57/185 reads (31%) | catalogued as COSV54091006; called by muse, mutect2, varscan2
- CABIN1 | c.4514G>A p.R1505Q | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1428169514; called by muse, mutect2, varscan2
- CABIN1 | c.4733C>T p.T1578I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV54091019; called by muse, mutect2, varscan2
- CABP4 | c.422T>G p.F141C | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56888586; called by muse, mutect2, varscan2
- CACNA1A | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV64215052; called by muse, mutect2, varscan2
- CACNA1C | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV59784709; called by muse, mutect2, varscan2
- CACNA1E | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 189/421 reads (45%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.932); catalogued as COSV62439019; called by muse, mutect2, varscan2
- CACNA1E | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV62439134; called by muse, mutect2, varscan2
- CACNA1S | c.5045C>T p.S1682F | Missense Mutation (SNP) | VAF 111/362 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV62945012; called by muse, mutect2, varscan2
- CACNA2D2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 144/390 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV56570288; called by muse, mutect2, varscan2
- CALHM5 | c.648G>C p.K216N | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62068839; called by muse, mutect2, varscan2
- CALHM6 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV63991450, COSV63991868; called by muse, mutect2, varscan2
- CALML3 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV59449378; called by muse, mutect2, varscan2
- CAMK2D | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV56441039; called by muse, mutect2, varscan2
- CAMKV | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV56558494; called by muse, mutect2, varscan2
- CAND1 | c.3004C>T p.P1002S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV73389817; called by muse, mutect2, varscan2
- CAP2 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57738576; called by muse, mutect2, varscan2
- CAPN12 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV61015770; called by muse, mutect2, varscan2
- CARD10 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV52660974; called by muse, mutect2, varscan2
- CARD10 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs866057374, COSV52656761; called by muse, mutect2, varscan2
- CARD9 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59999495; called by muse, mutect2, varscan2
- CARMIL2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1567627911, COSV58033199; called by muse, mutect2, varscan2
- CARMIL3 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs1384972833, COSV57728947; called by muse, mutect2, varscan2
- CATSPERG | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53054964; called by muse, mutect2, varscan2
- CBFA2T3 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV51934143; called by muse, mutect2, varscan2
- CBLB | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs967246502, COSV51439067; called by muse, mutect2, varscan2
- CCDC102A | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV50780243; called by muse, mutect2, varscan2
- CCDC141 | c.2222T>C p.V741A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.162); catalogued as COSV55384798; called by mutect2, varscan2
- CCDC150 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV55879804; called by muse, mutect2, varscan2
- CCDC163 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV59158420; called by muse, mutect2, varscan2
- CCDC66 | c.2272C>T p.P758S (on ENST00000394672 / NM_001353147.1; = p.P724S on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.214); catalogued as COSV58310920; called by muse, mutect2, varscan2
- CCDC73 | c.3017T>C p.F1006S | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58806632; called by muse, mutect2, varscan2
- CCDC87 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1377905182, COSV59581174; called by muse, mutect2, varscan2
- CCDC88B | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.979); catalogued as rs762055626, COSV57268792; called by muse, mutect2, varscan2
- CCIN | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58726032; called by muse, mutect2, varscan2
- CCNQ | c.429+1G>C p.X143_splice | Splice Site (SNP) | VAF 83/108 reads (77%) | catalogued as COSV52343827, COSV52344210, COSV52346069; called by muse, mutect2, varscan2
- CCR6 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV59476555; called by muse, mutect2, varscan2
- CD163L1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760772076, COSV58026525; called by muse, mutect2, varscan2
- CD163L1 | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 61/186 reads (33%) | catalogued as COSV58026540; called by muse, mutect2, varscan2
- CD163L1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.416); catalogued as COSV100550681, COSV58026549; called by muse, mutect2, varscan2
- CD177 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1403901096; called by muse, mutect2, varscan2
- CD200R1L | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV68005110; called by muse, mutect2, varscan2
- CD207 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868962938, COSV69651705; called by muse, mutect2, varscan2
- CD27 | c.449-1G>A p.X150_splice | Splice Site (SNP) | VAF 63/164 reads (38%) | catalogued as COSV56949049; called by muse, mutect2, varscan2
- CD300LF | c.231G>T p.R77S | Missense Mutation (SNP) | VAF 223/443 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV56899734; called by muse, mutect2, varscan2
- CD33 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV51805590; called by muse, mutect2, varscan2
- CD99L2 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 64/80 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV57988947; called by muse, mutect2, varscan2
- CDC20B | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs367903017, COSV57057831; called by muse, mutect2, varscan2
- CDC25A | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV56772688; called by muse, mutect2, varscan2
- CDC42BPA | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62024637; called by muse, mutect2, varscan2
- CDH10 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570603, COSV52576617; called by muse, mutect2, varscan2
- CDH15 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747232960, COSV57028485; called by muse, mutect2, varscan2
- CDH18 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs773516015, COSV56907624, COSV56927248; called by muse, mutect2, varscan2
- CDH19 | c.1058C>A p.S353Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50983842; called by muse, mutect2, varscan2
- CDH23 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54956847; called by muse, mutect2, varscan2
- CDH4 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 140/385 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV64679482; called by muse, mutect2, varscan2
- CDH5 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58520585; called by muse, mutect2, varscan2
- CDH5 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV58520591; called by muse, mutect2, varscan2
- CDH6 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs138589959, COSV54074759; called by muse, mutect2, varscan2
- CDH7 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs779910675, COSV59884974; called by muse, varscan2
- CDH7 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as rs776542846, COSV59897249; called by muse, varscan2
- CDK18 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV63729176; called by muse, mutect2
- CDO1 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV51666706; called by muse, mutect2, varscan2
- CDRT1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55414274; called by muse, mutect2, varscan2
- CEACAM19 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as COSV62551811; called by muse, mutect2
- CEACAM20 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.377); catalogued as COSV57603719; called by muse, mutect2, varscan2
- CECR2 | c.4154C>T p.S1385F (on ENST00000342247 / NM_001290047.2; = p.S1201F on NM_001290046.1) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52850531; called by muse, mutect2, varscan2
- CELA1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV53332153; called by muse, varscan2
- CENPF | c.1610T>C p.L537S | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65280066; called by muse, mutect2, varscan2
- CENPF | c.5726C>T p.S1909L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs763314217, COSV65280073; called by muse, mutect2, varscan2
- CENPQ | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as COSV59922742; called by muse, mutect2, varscan2
- CEP112 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV67145511; called by muse, mutect2, varscan2
- CEP128 | c.3095G>A p.G1032D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV99826305; called by muse, mutect2, varscan2
- CEP128 | c.3094G>A p.G1032S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99825650; called by muse, mutect2, varscan2
- CEP128 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); catalogued as rs140809152; called by muse, mutect2, varscan2
- CEP170B | c.2762C>T p.A921V (on ENST00000453495; = p.A850V on NM_015005.3) | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as COSV69027037; called by muse, mutect2, varscan2
- CEP290 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV58357765; called by muse, mutect2
- CEP85 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV53333349; called by muse, mutect2, varscan2
- CFAP45 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 106/326 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63649718, COSV63651540; called by muse, mutect2, varscan2
- CFAP53 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1267909982, COSV68353072; called by muse, mutect2, varscan2
- CFAP54 | c.6404C>T p.S2135F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV61576159; called by muse, mutect2, varscan2
- CFAP57 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1361443137, COSV65266261; called by muse, mutect2, varscan2
- CFAP70 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs751444822, COSV60282272; called by muse, mutect2, varscan2
- CFAP92 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs757196550, COSV54047483; called by muse, mutect2, varscan2
- CFHR3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as COSV66401552; called by muse, mutect2, varscan2
- CFTR | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758012554, COSV50125161; ClinVar: likely benign; called by muse, mutect2, varscan2
- CGNL1 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV55570024; called by muse, mutect2, varscan2
- CGNL1 | c.3629C>T p.A1210V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55577437; called by muse, mutect2, varscan2
- CHD5 | c.5200G>A p.D1734N | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1406342900, COSV52427660; called by muse, varscan2
- CHD8 | c.3034C>T p.L1012F (on ENST00000646647 / NM_001170629.2; = p.L733F on NM_020920.4) | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67869984, COSV67873117; called by muse, mutect2
- CHERP | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52224647, COSV52228303; called by muse, mutect2
- CHGB | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs560272361, COSV66760876; called by muse, varscan2
- CHMP6 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); catalogued as rs754281461, COSV57327775, COSV57328386; called by muse, mutect2, varscan2
- CIART | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV51742965; called by muse, mutect2, varscan2
- CILP | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56024016; called by muse, mutect2, varscan2
- CLCN5 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1557194903, COSV56587401; called by muse, mutect2, varscan2
- CLEC3A | c.241A>C p.T81P (on ENST00000651443; = p.T72P on NM_005752.6) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV55224375; called by muse, mutect2, varscan2
- CLEC4D | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55231300; called by muse, mutect2, varscan2
- CLIC3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 96/162 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65406942; called by muse, mutect2, varscan2
- CLK1 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV58436594; called by muse, mutect2, varscan2
- CLOCK | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV59405442; called by muse, mutect2, varscan2
- CLUAP1 | c.400-1G>A p.X134_splice | Splice Site (SNP) | VAF 37/69 reads (54%) | catalogued as COSV58895444; called by muse, mutect2, varscan2
- CLVS2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs750382549, COSV51562393, COSV51567732; called by muse, mutect2, varscan2
- CMYA5 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV71410450; called by muse, varscan2
- CMYA5 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV71410453; called by muse, varscan2
- CMYA5 | c.3208C>T p.P1070S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.645); catalogued as COSV71410459; called by muse, mutect2, varscan2
- CMYA5 | c.4819C>A p.P1607T | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV101483855; called by muse, mutect2, varscan2
- CMYA5 | c.5136A>T p.E1712D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV71410462; called by muse, mutect2
- CMYA5 | c.7373A>C p.D2458A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.044); catalogued as COSV71410466; called by muse, mutect2, varscan2
- CNGA3 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs746563618, COSV55629238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGB1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs764961610, COSV51908482; called by muse, mutect2, varscan2
- CNGB3 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as rs748386255, COSV60688044, COSV60700356; called by muse, mutect2, varscan2
- CNN1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52957238; called by muse, mutect2, varscan2
- CNPY4 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53542095; called by muse, mutect2, varscan2
- CNR2 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV65694135, COSV65694994; called by muse, mutect2, varscan2
- CNTD1 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV59312983; called by muse, mutect2, varscan2
- CNTN5 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.274); catalogued as rs867263470, COSV54275457; called by muse, mutect2
- CNTN6 | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV63167973, COSV63171452; called by muse, mutect2, varscan2
- CNTN6 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs778554523, COSV63193551; called by muse, mutect2, varscan2
- CNTNAP2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.185); catalogued as COSV62158693; called by muse, mutect2, varscan2
- CNTNAP2 | c.3269A>G p.N1090S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV62272386; called by muse, mutect2, varscan2
- CNTNAP5 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs898780015, COSV70515091, COSV70518246; called by muse, mutect2, varscan2
- COBLL1 | c.3047G>A p.G1016D (on ENST00000392717; = p.G978D on NM_014900.5) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV52078237; called by muse, mutect2, varscan2
- COL11A1 | c.4205G>A p.G1402E | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62172996; called by muse, mutect2, varscan2
- COL14A1 | c.4216C>T p.P1406S | Missense Mutation (SNP) | VAF 86/148 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0.15); catalogued as COSV52871992; called by muse, mutect2, varscan2
- COL1A1 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV56810542; called by muse, mutect2, varscan2
- COL2A1 | c.2463+2T>G p.X821_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV61535556; called by muse, mutect2, varscan2
- COL3A1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV58598349; called by muse, mutect2, varscan2
- COL4A3 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1312532, COSV67418388; called by muse, mutect2, varscan2
- COL4A3 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV67421665; called by muse, mutect2, varscan2
- COL5A1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 93/153 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65668220; called by muse, mutect2, varscan2
- COL6A3 | c.8021C>T p.S2674F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.339); catalogued as rs1169456064, COSV55110075; called by muse, mutect2, varscan2
- COL6A5 | c.7412G>A p.R2471Q (on ENST00000312481; = p.R2467Q on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370340112, COSV55194713; called by muse, mutect2, varscan2
- COL6A6 | c.5020G>A p.G1674R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62040452; called by muse, mutect2, varscan2
- COL7A1 | c.4637G>A p.G1546E | Missense Mutation (SNP) | VAF 109/302 reads (36%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.887); catalogued as COSV60404659; called by muse, mutect2, varscan2
- COL7A1 | c.3484G>A p.V1162I | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1260291089, COSV60404667; called by muse, mutect2, varscan2
- COL7A1 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as COSV60404673; called by muse, mutect2, varscan2
- COL9A1 | c.876C>G p.D292E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs199570724, COSV57888799, COSV57895532; called by muse, mutect2, varscan2
- COL9A2 | c.1010G>A p.G337D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101028391, COSV65624414; called by muse, mutect2, varscan2
- CORO1A | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54632382; called by muse, mutect2, varscan2
- CORO2A | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763508368, COSV59665362; called by muse, mutect2, varscan2
- COX15 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462019991, COSV50013585; called by muse, mutect2, varscan2
- CPEB1 | c.1216G>A p.G406S (on ENST00000617958; = p.G346S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV55618189, COSV55622281; called by muse, mutect2, varscan2
- CR2 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV65510281; called by muse, mutect2, varscan2
- CRACR2A | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV52919653; called by muse, mutect2, varscan2
- CRIM1 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs1261661576, COSV54874597; called by muse, mutect2, varscan2
- CRISPLD1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV51550640; called by muse, mutect2, varscan2
- CRNN | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55124473; called by muse, mutect2, varscan2
- CRTC1 | c.243G>A p.Q81= | Splice Region (SNP) | VAF 20/57 reads (35%) | catalogued as COSV58724468; called by muse, mutect2, varscan2
- CRX | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV55757757; called by muse, mutect2, varscan2
- CRYBG1 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.963); catalogued as COSV64815334; called by muse, mutect2, varscan2
- CRYBG2 | c.3710C>T p.P1237L | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs1409266832, COSV57491153; called by muse, mutect2, varscan2
- CSMD1 | c.1843A>T p.I615F (on ENST00000520002; = p.I614F on NM_033225.6) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV59399281; called by muse, mutect2, varscan2
- CSMD3 | c.9431G>A p.G3144E (on ENST00000297405 / NM_001363185.1; = p.G2975E on NM_052900.3) | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs558471150, COSV52351421; called by muse, mutect2, varscan2
- CSMD3 | c.9128G>A p.G3043E (on ENST00000297405 / NM_001363185.1; = p.G2874E on NM_052900.3) | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV52351437; called by muse, mutect2, varscan2
- CSMD3 | c.538A>T p.N180Y | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV52351449; called by muse, mutect2, varscan2
- CSN2 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV61992876; called by muse, mutect2, varscan2
- CST9L | c.158T>C p.F53S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65408498; called by muse, mutect2, varscan2
- CSTF2 | c.1037A>T p.Y346F | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV65895419; called by muse, mutect2, varscan2
- CT83 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 82/120 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV64141088; called by muse, mutect2, varscan2
- CTSS | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV64567255; called by muse, mutect2, varscan2
- CUL9 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV52736377; called by muse, mutect2, varscan2
- CUX1 | c.142-1G>A p.X48_splice (on ENST00000292535 / NM_181552.4; = p.X59_splice on NM_001913.5) | Splice Site (SNP) | VAF 30/98 reads (31%) | catalogued as COSV52894645; called by muse, mutect2, varscan2
- CUX1 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52895461; called by muse, mutect2, varscan2
- CUX2 | c.1787A>G p.K596R | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55651369; called by muse, mutect2, varscan2
- CWH43 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs548931558, COSV56939731; called by muse, mutect2, varscan2
- CXCL12 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as COSV59109492; called by muse, mutect2, varscan2
- CXCR2 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs200127100, COSV59279841; called by muse, mutect2, varscan2
- CYBC1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1203313642, COSV60673690; called by muse, mutect2
- CYLC1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61416831; called by muse, mutect2, varscan2
- CYLC1 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV61415873; called by muse, mutect2, varscan2
- CYP2A13 | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs866002403, COSV57840570; called by muse, mutect2, varscan2
- CYP2C8 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV64877499; called by muse, mutect2, varscan2
- CYP2E1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53315914; called by muse, mutect2, varscan2
- CYP2E1 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV53315170; called by muse, mutect2, varscan2
- CYP2W1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256068931, COSV58271902; called by muse, mutect2, varscan2
- CYP4A11 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs150346297; called by muse, mutect2, varscan2
- CYP7B1 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.1); catalogued as COSV59598827; called by muse, mutect2, varscan2
- DAD1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.992); catalogued as COSV51664069; called by muse, mutect2, varscan2
- DAPP1 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV56450546, COSV56451446; called by muse, mutect2, varscan2
- DBX1 | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs866536142, COSV57055580; called by muse, mutect2, varscan2
- DBX2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60340184; called by muse, mutect2, varscan2
- DCAF11 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58111322; called by muse, mutect2, varscan2
- DCC | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.405); catalogued as rs1472053367, COSV59132009; called by muse, mutect2, varscan2
- DCC | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV59144899; called by muse, mutect2, varscan2
- DCC | c.2632G>A p.V878M | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as COSV59144915; called by muse, mutect2, varscan2
- DCDC1 | c.1718A>C p.Q573P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774604232, COSV60862772; called by muse, mutect2, varscan2
- DCDC1 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as rs755906212, COSV60842629, COSV60862780; called by muse, mutect2
- DCDC1 | c.944A>T p.K315I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV60850295, COSV60862791; called by muse, mutect2
- DCX | c.105T>A p.C35* | Nonsense Mutation (SNP) | VAF 64/99 reads (65%) | catalogued as COSV57576507; called by muse, mutect2, varscan2
- DDIAS | c.1363C>T p.H455Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV61271325, COSV61271344; called by muse, mutect2, varscan2
- DDO | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); catalogued as COSV64469712, COSV64470829; called by muse, mutect2, varscan2
- DDX56 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51838312; called by muse, mutect2, varscan2
- DDX60 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs144653089; called by muse, mutect2, varscan2
- DDX60L | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as rs774749148, COSV52724128; called by muse, mutect2
- DEFB125 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 122/361 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV66703736; called by muse, mutect2
- DGCR2 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV54223338; called by muse, mutect2, varscan2
- DHDH | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs768908579, COSV55481883; called by muse, mutect2, varscan2
- DHX32 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52944067; called by muse, mutect2, varscan2
- DHX32 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52944077; called by muse, mutect2, varscan2
- DHX38 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs1377367652, COSV51701622; called by muse, mutect2, varscan2
- DLG5 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV64950421; called by muse, mutect2, varscan2
- DLGAP2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs763122940, COSV70104485; called by muse, mutect2, varscan2
- DMBT1 | c.5383G>A p.D1795N (on ENST00000338354 / NM_001377530.1; = p.D1038N on NM_004406.3) | Missense Mutation (SNP) | VAF 146/487 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760683143, COSV57535850, COSV57547017; called by muse, mutect2, varscan2
- DNAH11 | c.6215C>T p.S2072F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60987832, COSV99080612; called by muse, mutect2, varscan2
- DNAH11 | c.12746A>T p.E4249V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60987853; called by muse, mutect2
- DNAH12 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.702); catalogued as rs1202789062, COSV100244906, COSV60859532; called by muse, mutect2, varscan2
- DNAH17 | c.9704C>G p.S3235C | Missense Mutation (SNP) | VAF 283/614 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67762682; called by muse, mutect2, varscan2
- DNAH17 | c.4895G>A p.G1632E | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67762700; called by muse, mutect2, varscan2
- DNAH5 | c.8597G>A p.G2866E | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54259110; called by muse, mutect2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH5 | c.6447T>G p.V2149= | Splice Region (SNP) | VAF 38/64 reads (59%) | catalogued as COSV54204864; called by muse, mutect2, varscan2
- DNAH7 | c.5620C>T p.R1874* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as rs267599141, COSV56755304; called by muse, mutect2, varscan2
- DNAH7 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV56791596; called by muse, mutect2, varscan2
- DNAH8 | c.5726C>T p.S1909L | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59487065; called by muse, mutect2, varscan2
- DNAH8 | c.11677G>C p.V3893L | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV59487085; called by muse, mutect2, varscan2
- DNAI1 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV54285683; called by muse, mutect2, varscan2
- DNAJC16 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV65449698; called by muse, mutect2, varscan2
- DNAJC9 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV54355437; called by muse, mutect2, varscan2
- DNER | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as COSV59179480; called by muse, mutect2, varscan2
- DNHD1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs886653281; called by muse, mutect2, varscan2
- DOC2A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363595453, COSV58753144; called by muse, mutect2, varscan2
- DOCK10 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51431355; called by muse, mutect2, varscan2
- DOCK4 | c.5836G>A p.G1946R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.352); catalogued as COSV70241648, COSV70244602; called by muse, mutect2, varscan2
- DOCK6 | c.5761G>A p.E1921K | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as rs924103184, COSV53923977, COSV99626885; called by muse, mutect2, varscan2
- DOK6 | c.410-1G>A p.X137_splice | Splice Site (SNP) | VAF 36/88 reads (41%) | catalogued as COSV66927991, COSV66939002; called by muse, mutect2, varscan2
- DOP1B | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67697095; called by muse, mutect2, varscan2
- DRAM2 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54415971; called by muse, mutect2, varscan2
- DRC7 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV61058426; called by muse, mutect2, varscan2
- DSCAML1 | c.2674G>A p.D892N (on ENST00000321322; = p.D832N on NM_020693.4) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV58388648, COSV58405490; called by muse, mutect2, varscan2
- DSG3 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57130441; called by muse, mutect2, varscan2
- DTX1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55660626, COSV99921629; called by muse, mutect2, varscan2
- DYNC1LI2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV50757141; called by muse, mutect2, varscan2
- DYNC2H1 | c.10138C>T p.P3380S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as COSV62089061; called by muse, mutect2, varscan2
- DZIP1 | c.2251G>A p.E751K (on ENST00000347108; = p.E732K on NM_014934.5) | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV61270150; called by muse, varscan2
- E2F4 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58878376; called by muse, mutect2, varscan2
- EBF3 | c.1247C>T p.P416L (on ENST00000355311 / NM_001375392.1; = p.P407L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62483198; called by muse, mutect2, varscan2
- EFCAB12 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.457); catalogued as COSV58178383; called by muse, mutect2, varscan2
- EFCAB3 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172482693, COSV59503685; called by muse, mutect2, varscan2
- EFHB | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 170/586 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV55551908; called by muse, mutect2, varscan2
- EGFLAM | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs180977046, COSV59311323; called by muse, mutect2
- EHBP1 | c.1862T>C p.V621A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.497); catalogued as rs1240945757, COSV50446028; called by muse, mutect2, varscan2
- EIF4G1 | c.4376G>A p.R1459Q (on ENST00000346169 / NM_198241.3; = p.R1264Q on NM_004953.5) | Missense Mutation (SNP) | VAF 100/143 reads (70%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs369679218; called by muse, mutect2
- ELAPOR2 | c.3079C>T p.P1027S (on ENST00000450689 / NM_001142749.3; = p.P860S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.168); catalogued as COSV51893175; called by muse, mutect2, varscan2
- ELF1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.219); catalogued as rs1323341015; called by muse, mutect2, varscan2
- ELMO3 | c.2275C>T p.P759S (on ENST00000652269; = p.P706S on NM_024712.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422070220, COSV58528703; called by muse, mutect2, varscan2
- ELN | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 199/775 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); catalogued as COSV52717000; called by muse, mutect2, varscan2
- ELOVL5 | c.11T>A p.F4Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV58653852; called by muse, mutect2, varscan2
- ELOVL7 | c.234T>A p.F78L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV70918837; called by muse, mutect2, varscan2
- EMB | c.863A>T p.K288I | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV57485423; called by muse, mutect2, varscan2
- EMB | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV57485434; called by muse, mutect2, varscan2
- ENPEP | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV54451225; called by muse, mutect2, varscan2
- ENPP4 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs775632459, COSV58090385; called by muse, mutect2, varscan2
- ENTR1 | c.1079C>T p.S360F (on ENST00000357365 / NM_001039707.2; = p.S337F on NM_006643.4) | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV53743855; called by muse, mutect2, varscan2
- EPHA2 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV64455105; called by muse, mutect2, varscan2
- EPHA6 | c.2612G>A p.G871E (on ENST00000389672 / NM_001080448.3; = p.G263E on NM_173655.4) | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67595266; called by muse, mutect2, varscan2
- EPHB4 | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs375150649; called by muse, mutect2, varscan2
- EPHB4 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.688); catalogued as rs1244049178, COSV62270914; called by muse, mutect2, varscan2
- EPPK1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); catalogued as rs369364428; called by muse, varscan2
- ERBB4 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61503604; called by muse, mutect2, varscan2
- ERCC1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); catalogued as rs1423976551, COSV50005830; called by muse, mutect2, varscan2
- ERICH3 | c.4571C>T p.S1524F | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs745496149, COSV58617827; called by muse, mutect2, varscan2
- ERICH3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1159893217, COSV58618484; called by muse, mutect2, varscan2
- ERLIN1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as rs780862850, COSV100962296, COSV64941532; called by muse, mutect2, varscan2
- ERN2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868383333, COSV56831808; called by muse, mutect2, varscan2
- ESPNL | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV58039132; called by muse, mutect2, varscan2
- ESRRA | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.857); catalogued as COSV50008557; called by muse, mutect2, varscan2
- ESRRG | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63185611; called by muse, mutect2, varscan2
- ETHE1 | c.763T>C p.*255Rext*22 | Nonstop Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as COSV52672998; called by muse, varscan2
- EVC2 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60403826; called by muse, mutect2, varscan2
- EXO1 | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV62220411; called by muse, mutect2, varscan2
- EXOC1 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV62122379; called by muse, mutect2, varscan2
- EXOC6B | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs749876156, COSV55550273; called by muse, mutect2, varscan2
- EXPH5 | c.2164A>G p.K722E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs1431133611, COSV56209580; called by muse, mutect2, varscan2
- EXPH5 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1200513110, COSV56206767; called by muse, mutect2, varscan2
- F9 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54382889; called by muse, mutect2, varscan2
- F9 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as CM940494, COSV54382897; called by muse, mutect2, varscan2
- FAAP100 | c.1603T>C p.F535L | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV59888302; called by muse, mutect2, varscan2
- FAIM | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.143); catalogued as COSV58159117, COSV58159991; called by muse, mutect2, varscan2
- FAM110C | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs752382726, COSV59656720; called by muse, mutect2, varscan2
- FAM120C | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as COSV60263135; called by muse, mutect2, varscan2
- FAM135B | c.3574G>A p.D1192N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52717937; called by muse, mutect2, varscan2
- FAM151A | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56366775; called by muse, mutect2, varscan2
- FAM170A | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV58927841; called by muse, mutect2, varscan2
- FAM184A | c.1333-1G>A p.X445_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV58859550; called by muse, mutect2
- FAM47C | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs376309609, COSV63729204; called by muse, mutect2, varscan2
- FAM47C | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV63731119; called by muse, mutect2, varscan2
- FAM71F1 | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV59375188; called by muse, mutect2, varscan2
- FAM83B | c.961A>T p.N321Y | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60928079; called by muse, mutect2, varscan2
- FAM83B | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as COSV60920792; called by muse, mutect2, varscan2
- FAM91A1 | c.1859T>G p.F620C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV58240422; called by muse, mutect2, varscan2
- FAR1 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV61387034; called by muse, mutect2, varscan2
- FAT2 | c.7168G>C p.E2390Q | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55832080; called by muse, mutect2, varscan2
- FAT3 | c.2460T>A p.N820K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.047); catalogued as COSV53188828; called by muse, mutect2, varscan2
- FAT3 | c.12514T>C p.F4172L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.712); catalogued as COSV53188845; called by muse, mutect2, varscan2
- FAT4 | c.4838C>T p.S1613L | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs956160354, COSV67903155; called by muse, mutect2, varscan2
- FAT4 | c.11672C>T p.P3891L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs747656842, COSV58714037; called by muse, mutect2, varscan2
- FBLN5 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 42/69 reads (61%) | catalogued as COSV50905825, COSV50911215; called by muse, mutect2, varscan2
- FBLN7 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55617616; called by muse, mutect2, varscan2
- FBN1 | c.7070C>T p.P2357L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.272); catalogued as COSV57326071; called by muse, mutect2, varscan2
- FBN2 | c.3839C>T p.S1280L | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs200481467; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- FBN2 | c.3785G>A p.G1262E | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52551557; called by muse, varscan2
- FBN3 | c.8063G>A p.R2688Q | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs375603937; called by muse, varscan2
- FBXL6 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372210529; called by muse, mutect2, varscan2
- FBXL7 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV61654919; called by muse, mutect2, varscan2
- FBXO10 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368530132; called by muse, mutect2, varscan2
- FBXO36 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV52281976; called by muse, mutect2, varscan2
- FBXO7 | c.1411A>G p.T471A | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56682246; called by muse, mutect2, varscan2
- FBXW8 | c.881T>C p.V294A (on ENST00000309909; = p.V332A on NM_012174.1) | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV59304454; called by muse, mutect2, varscan2
- FCHSD1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV71302185; called by muse, mutect2, varscan2
- FCMR | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as rs762880718, COSV65569929; called by muse, mutect2, varscan2
- FCRL1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs777013547, COSV63827808; called by muse, mutect2, varscan2
- FCRL5 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.406); catalogued as COSV100709441, COSV62521502; called by muse, mutect2, varscan2
- FDCSP | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs752862647, COSV58765483; called by muse, mutect2, varscan2
- FGA | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866653042, COSV57394697; called by muse, mutect2, varscan2
- FGD3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV61600523; called by muse, mutect2, varscan2
- FGD5 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.197); catalogued as COSV53254916; called by muse, mutect2, varscan2
- FGD6 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59698099; called by muse, mutect2, varscan2
- FGF6 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 60/228 reads (26%) | catalogued as COSV57405659; called by muse, mutect2, varscan2
- FHL5 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100459504, COSV58741355; called by muse, mutect2, varscan2
- FHOD1 | c.1742del p.G581Efs*47 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV50762189; called by mutect2, pindel*, varscan2
- FKBP15 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 115/187 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1280092532, COSV53040792; called by muse, mutect2, varscan2
- FLNA | c.7112C>T p.P2371L (on ENST00000369850 / NM_001110556.2; = p.P2363L on NM_001456.3) | Missense Mutation (SNP) | VAF 128/158 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61053566; called by muse, mutect2, varscan2
- FLNA | c.4483G>A p.E1495K | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV61053576; called by muse, mutect2, varscan2
- FLNB | c.6824C>T p.P2275L | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55899823; called by muse, mutect2, varscan2
- FLNC | c.6308C>T p.T2103I | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100367709, COSV57967260; called by muse, mutect2, varscan2
- FLYWCH1 | c.1706C>T p.P569L (on ENST00000253928 / NM_001308068.2; = p.P568L on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs748711943, COSV54150535; called by muse, mutect2, varscan2
- FMNL2 | c.2540G>A p.S847N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1210914769, COSV56506926; called by muse, mutect2
- FMO1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100707672, COSV61448079; called by muse, mutect2, varscan2
- FNBP4 | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55453007; called by muse, mutect2, varscan2
- FNDC3A | c.1733C>T p.S578L (on ENST00000492622 / NM_001079673.2; = p.S522L on NM_014923.5) | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV68135560; called by muse, mutect2, varscan2
- FOXRED2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53401927; called by muse, mutect2
- FOXRED2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV53401934; called by muse, mutect2, varscan2
- FPR3 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59332765; called by muse, mutect2, varscan2
- FRAS1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV53658344; called by muse, mutect2, varscan2
- FRAS1 | c.3130C>T p.H1044Y | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53633867; called by muse, mutect2, varscan2
- FREM1 | c.4996G>A p.D1666N | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1475134475, COSV66530609; called by muse, mutect2, varscan2
- FREM1 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.084); catalogued as COSV101085702, COSV66532097; called by muse, mutect2, varscan2
- FREM1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV101084008, COSV66532108; called by muse, mutect2, varscan2
- FRMD7 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213344421, COSV53748805; called by muse, mutect2, varscan2
- FRMPD2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV59724810; called by muse, mutect2, varscan2
- FRMPD2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs900679275, COSV59724819; called by muse, mutect2, varscan2
- FRMPD3 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV52198422; called by muse, mutect2, varscan2
- FRS2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54727770; called by muse, mutect2, varscan2
- FRY | c.4882C>T p.P1628S | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66582289; called by muse, mutect2, varscan2
- FSHR | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV58637683; called by muse, mutect2, varscan2
- FYB1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 125/242 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60958048; called by muse, mutect2, varscan2
- FYCO1 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV56120865; called by muse, mutect2, varscan2
- FYCO1 | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56120875; called by muse, mutect2, varscan2
- G6PC | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV53833327; called by muse, varscan2
- GAB1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs761299664, COSV53761786; called by muse, mutect2, varscan2
- GABBR1 | c.2594A>G p.E865G | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63545038; called by muse, mutect2, varscan2
- GABRA2 | c.1324A>T p.N442Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62921298; called by muse, mutect2, varscan2
- GABRA4 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51936774; called by muse, mutect2, varscan2
- GABRG1 | c.660G>A p.W220* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs267600166, COSV54951101; called by muse, mutect2, varscan2
- GAD1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs150945113; called by muse, mutect2, varscan2
- GALNT18 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1361424339, COSV57159664; called by muse, mutect2, varscan2
- GAS2L2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200874463; called by muse, mutect2, varscan2
- GAS2L3 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1290761534, COSV57159560; called by muse, mutect2, varscan2
- GATA2 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs770511115, COSV62003207, COSV62007964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBF1 | c.5282C>T p.P1761L (on ENST00000369983 / NM_001377137.1; = p.P1760L on NM_004193.3) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs777308112, COSV64149970; called by muse, mutect2, varscan2
- GCLM | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV64687668; called by muse, mutect2, varscan2
- GCN1 | c.7148C>T p.P2383L | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV56116226; called by muse, mutect2, varscan2
- GCOM1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51101729; called by muse, mutect2, varscan2
- GDF5 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs34534075; called by muse, mutect2, varscan2
- GDPD5 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV61130914; called by muse, mutect2, varscan2
- GIMAP8 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as rs1338376937, COSV100217367, COSV56230030; called by muse, mutect2, varscan2
- GJA8 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53789781, COSV53791306; called by muse, mutect2, varscan2
- GK2 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1221291638, COSV62627253; called by muse, mutect2, varscan2
- GLB1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV56568895; called by muse, mutect2, varscan2
- GLP2R | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV52330547; called by muse, mutect2, varscan2
- GLP2R | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52324942, COSV52330559; called by muse, mutect2, varscan2
- GLRA4 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 126/171 reads (74%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV65456591, COSV65457201; called by muse, mutect2, varscan2
- GLRB | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52423660; called by muse, mutect2, varscan2
- GLT8D2 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62563541; called by muse, mutect2, varscan2
- GLUD2 | c.1676A>T p.*559Lext*5 | Nonstop Mutation (SNP) | VAF 112/150 reads (75%) | catalogued as COSV60153496; called by muse, mutect2, varscan2
- GMEB1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV53794888; called by muse, mutect2, varscan2
- GNB1L | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749751065, COSV61550347; called by muse, mutect2, varscan2
- GNS | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV50697294; called by muse, mutect2, varscan2
- GPATCH1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.203); catalogued as rs767665955, COSV50133197; called by muse, mutect2, varscan2
- GPATCH2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65128806; called by muse, mutect2, varscan2
- GPATCH8 | c.3854C>T p.P1285L | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as COSV59199813; called by muse, mutect2, varscan2
- GPR1 | c.726T>G p.S242R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV67977752; called by muse, mutect2, varscan2
- GPR139 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs748140778, COSV58502244, COSV58505631; called by muse, varscan2
- GPR153 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV64938422, COSV64939129; called by muse, mutect2, varscan2
- GPR158 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs367760867, COSV66266673; called by muse, mutect2, varscan2
- GPR37 | c.1427G>T p.C476F | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as COSV58260415; called by muse, mutect2, varscan2
- GPR37 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV58260430; called by muse, mutect2, varscan2
- GPRC6A | c.2510T>A p.I837N | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59956623; called by muse, mutect2, varscan2
- GPX6 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs761607451, COSV62659438; called by muse, mutect2, varscan2
- GPX6 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV62659445; called by muse, mutect2, varscan2
- GREB1 | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.962); catalogued as COSV52198535; called by muse, mutect2, varscan2
- GRHL1 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1385427526, COSV100258027, COSV61411495; called by muse, mutect2, varscan2
- GRHL2 | c.1612G>A p.V538M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52548167, COSV52556392; called by muse, mutect2, varscan2
- GRID2 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV56284652; called by muse, mutect2, varscan2
- GRIK5 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV53487559; called by muse, mutect2, varscan2
- GRIN2D | c.2135C>T p.T712I | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54382879; called by muse, mutect2, varscan2
- GRINA | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs1554750379, COSV57300749; called by muse, mutect2, varscan2
- GRIP2 | c.2027G>A p.R676Q (on ENST00000619221; = p.R579Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as rs369295468; called by muse, mutect2, varscan2
- GRM3 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV100862537; called by muse, mutect2
- GRM3 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs867538929, COSV64480361; called by muse, mutect2
- GRM6 | c.1924G>A p.V642M | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV51451173; called by muse, mutect2, varscan2
- GRM6 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs754777968, COSV51451186; called by muse, mutect2, varscan2
- GRM7 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.974); catalogued as COSV100738599, COSV63130639, COSV63139535; called by muse, mutect2, varscan2
- GRM8 | c.2309C>G p.T770R | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147639816, COSV100282011; called by muse, varscan2
- GRM8 | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs754911383, COSV58854797; called by muse, varscan2
- GRM8 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 48/182 reads (26%) | catalogued as COSV58835482; called by muse, mutect2, varscan2
- GRWD1 | c.1227C>A p.F409L | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53521215; called by muse, mutect2, varscan2
- GRXCR1 | c.223A>G p.N75D | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV67675553; called by muse, mutect2, varscan2
- GRXCR2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV65062072; called by muse, mutect2, varscan2
- GSDMC | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.063); catalogued as COSV52695576; called by muse, mutect2, varscan2
- GSPT2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 116/156 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61215441; called by muse, mutect2, varscan2
- GTSE1 | c.292T>C p.F98L | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV71890088; called by muse, mutect2, varscan2
- GUCY1A2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56505926; called by muse, mutect2, varscan2
- GUCY2C | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53797012; called by muse, mutect2, varscan2
- H3C4 | c.203T>A p.F68Y | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV61912529; called by muse, mutect2, varscan2
- HAGH | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036350754, COSV101272494; called by muse, mutect2, varscan2
- HASPIN | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs758962184, COSV54000126; called by muse, mutect2, varscan2
- HBE1 | c.104T>A p.V35D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53079776, COSV53081727; called by muse, mutect2
- HCN1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV57495742; called by muse, mutect2, varscan2
- HDHD5 | c.1037G>T p.R346L (on ENST00000336737 / NM_033070.3; = p.R316L on NM_017829.5) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV50097706; called by muse, mutect2, varscan2
- HEATR1 | c.2103A>T p.K701N | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV63983648; called by muse, mutect2, varscan2
- HEATR4 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV58578260; called by muse, mutect2, varscan2
- HECTD4 | c.5706T>A p.D1902E | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV66398667, COSV66401712; called by muse, mutect2, varscan2
- HECW2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 94/304 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53677583; called by muse, mutect2, varscan2
- HEPHL1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs749277008, COSV59891479; called by muse, mutect2, varscan2
- HHIP | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV56845230; called by muse, mutect2, varscan2
- HHIP | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56845239; called by muse, mutect2, varscan2
- HHLA2 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs1272904239, COSV63320800; called by muse, mutect2, varscan2
- HHLA2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as rs267599525, COSV63317498; called by muse, mutect2, varscan2
- HID1 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV59352463; called by muse, mutect2, varscan2
- HK2 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1200570125, COSV51879926; called by muse, mutect2, varscan2
- HNF4A | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as CM021614, CM021615, COSV57390171; called by muse, mutect2, varscan2
- HNF4A | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs202073574, COSV57390196; called by muse, mutect2, varscan2
- HNF4G | c.772A>T p.K258* (on ENST00000354370 / NM_001330561.2; = p.K305* on NM_004133.5) | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV62974927; called by muse, mutect2, varscan2
- HNF4G | c.1012C>T p.H338Y (on ENST00000354370 / NM_001330561.2; = p.H385Y on NM_004133.5) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.703); catalogued as COSV62974934; called by muse, varscan2
- HNF4G | c.1090C>T p.H364Y (on ENST00000354370 / NM_001330561.2; = p.H411Y on NM_004133.5) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.487); catalogued as COSV62971901; called by muse, varscan2
- HNRNPM | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs1395239691, COSV55317786; called by muse, mutect2, varscan2
- HOXB3 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61145778; called by muse, mutect2, varscan2
- HRNR | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 140/314 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs202015055, COSV64263761; called by muse, mutect2, varscan2
- HRNR | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as rs753882729, COSV64263766; called by muse, mutect2, varscan2
- HS3ST3A1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.362); catalogued as rs1228822657, COSV52380133; called by muse, mutect2, varscan2
- HS3ST4 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs749218404, COSV58830788; called by muse, mutect2, varscan2
- HS3ST5 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs544926335, COSV57153927; called by muse, mutect2, varscan2
- HSD3B1 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 31/144 reads (22%) | catalogued as COSV52492756; called by muse, mutect2, varscan2
- HTR2C | c.33C>T p.F11= | Splice Region (SNP) | VAF 26/31 reads (84%) | catalogued as COSV52227414; called by muse, mutect2, varscan2
- HYAL4 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV56140734; called by muse, mutect2, varscan2
- HYDIN | c.9269G>A p.G3090E | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.124); catalogued as COSV59254430; called by muse, mutect2, varscan2
- HYDIN | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267604623, COSV55485377; called by muse, mutect2, varscan2
- HYOU1 | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68217631; called by muse, varscan2
- ICA1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55585829; called by muse, mutect2, varscan2
- IDO1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53713747; called by muse, mutect2, varscan2
- IFI44L | c.785A>T p.D262V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60729782; called by muse, mutect2, varscan2
- IFIT1B | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1455026168, COSV65663819; called by muse, mutect2, varscan2
- IFNA5 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 147/357 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1335529160, COSV52387784; called by muse, mutect2, varscan2
- IGF2BP3 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV51694960; called by muse, mutect2, varscan2
- IGKV2-24 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs746018812; called by muse, mutect2, varscan2
- IGLV5-52 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs567812504; called by muse, mutect2, varscan2
- IGLV9-49 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs112293276; called by muse, mutect2, varscan2
- IGSF1 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 83/120 reads (69%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.767); catalogued as rs1394841302, COSV63837608; called by muse, mutect2, varscan2
- IGSF21 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52146825; called by muse, mutect2, varscan2
- IGSF22 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs1358653725, COSV60030680, COSV60040034; called by muse, mutect2, varscan2
- IKZF3 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV53101470; called by muse, mutect2, varscan2
- IL17RD | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV56339173; called by muse, mutect2, varscan2
- IL1RL2 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51820055; called by muse, mutect2, varscan2
- IL21R | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV61973205; called by muse, mutect2, varscan2
- IL21R | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV61973213; called by muse, mutect2, varscan2
- IL27RA | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1294654521, COSV99652252; called by muse, mutect2, varscan2
- IL36A | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52084110; called by muse, mutect2, varscan2
- IL5RA | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV56526343, COSV99842741; called by muse, mutect2, varscan2
- IL7R | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs778728560, COSV57405607; called by muse, mutect2, varscan2
- ILDR1 | c.1072C>T p.P358S (on ENST00000344209 / NM_001199799.2; = p.P314S on NM_175924.4) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56546926; called by muse, mutect2, varscan2
- IMP3 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs1332420696, COSV59189840; called by muse, mutect2, varscan2
- INPP5D | c.424G>A p.E142K (on ENST00000445964 / NM_001017915.3; = p.E141K on NM_005541.5) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV100856893, COSV64035749; called by muse, mutect2, varscan2
- INPP5J | c.1378G>A p.A460T (on ENST00000331075 / NM_001284285.2; = p.A92T on NM_001002837.2) | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs767028605, COSV58511847; called by muse, mutect2, varscan2
- INSC | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756560550; called by muse, mutect2, varscan2
- IPO7 | c.2318T>G p.V773G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1190871701, COSV65687452; called by muse, mutect2, varscan2
- IQCA1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1176186919, COSV54515234; called by muse, mutect2, varscan2
- IQCF1 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs953574768; called by muse, mutect2, varscan2
- IRAK2 | c.1536G>A p.W512* | Nonsense Mutation (SNP) | VAF 49/132 reads (37%) | catalogued as rs867176963, COSV56536682; called by muse, mutect2, varscan2
- IRF6 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65419049; called by muse, mutect2, varscan2
- IRF7 | c.1313C>T p.S438F (on ENST00000397566; = p.S425F on NM_001572.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390666233, COSV99200748; called by muse, mutect2
- ISM1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.609); catalogued as COSV52602380; called by muse, mutect2, varscan2
- ITFG2 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs369647396; called by muse, mutect2, varscan2
- ITGA11 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV59882925; called by muse, mutect2, varscan2
- ITGA4 | c.2785G>A p.D929N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV59215187; called by muse, mutect2, varscan2
- ITGA5 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.866); catalogued as COSV53217826; called by muse, mutect2, varscan2
- ITGA5 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV53221400; called by muse, mutect2, varscan2
- ITGA7 | c.2875G>A p.E959K (on ENST00000555728; = p.E915K on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.916); catalogued as COSV57702591; called by muse, mutect2, varscan2
- ITGAE | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54001629; called by muse, mutect2, varscan2
- ITGAV | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894915282, COSV53720441; called by muse, mutect2, varscan2
- ITGB2 | c.1975G>A p.E659K (on ENST00000302347; = p.E635K on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758504990, COSV56612630; called by muse, mutect2, varscan2
- ITGB3 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71384908; called by muse, mutect2, varscan2
- ITPR1 | c.3239C>T p.A1080V (on ENST00000354582; = p.A1065V on NM_002222.7) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1391996488, COSV57008459; called by muse, varscan2
- ITPR2 | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs773730966, COSV67264269; called by muse, mutect2, varscan2
- JAKMIP2 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 76/172 reads (44%) | catalogued as COSV54617773; called by muse, mutect2, varscan2
- JAKMIP2 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV54613248; called by muse, mutect2, varscan2
- JCAD | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV64762154; called by muse, mutect2, varscan2
- JCAD | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64762157; called by muse, mutect2, varscan2
- JMJD4 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV59917909; called by muse, mutect2, varscan2
- JPH1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60615718; called by muse, mutect2, varscan2
- KANK4 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV62989886; called by muse, mutect2, varscan2
- KANK4 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV62988920; called by muse, mutect2, varscan2
- KATNBL1 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.13); catalogued as COSV56623134, COSV56626046; called by muse, mutect2, varscan2
- KBTBD13 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV71351833; called by muse, mutect2, varscan2
- KCNA10 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365250697, COSV63905580; called by muse, mutect2, varscan2
- KCNA2 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV60371735; called by muse, mutect2, varscan2
- KCNB1 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65565845, COSV65571021; called by muse, mutect2, varscan2
- KCNB2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV73053458; called by muse, mutect2, varscan2
- KCND2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.523); catalogued as rs1044289793, COSV100474141, COSV58569920; called by muse, mutect2, varscan2
- KCNH5 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100526719, COSV59777552, COSV59780024; called by muse, mutect2, varscan2
- KCNH6 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV59008617; called by muse, mutect2, varscan2
- KCNJ15 | c.823A>G p.K275E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.415); catalogued as COSV60812331; called by muse, mutect2, varscan2
- KCNJ3 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.238); catalogued as rs750258804, COSV54546980; called by muse, mutect2, varscan2
- KCNK18 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.005); catalogued as COSV57973609; called by muse, mutect2, varscan2
- KCNQ3 | c.1166A>T p.N389I | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66484557; called by muse, mutect2, varscan2
- KCTD16 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs776301270, COSV72580946; called by muse, mutect2, varscan2
- KDM5A | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66997026; called by muse, mutect2, varscan2
- KEL | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV62334398; called by muse, mutect2, varscan2
- KHDC1 | c.649C>T p.P217S (on ENST00000370384 / NM_001251874.2; = p.P144S on NM_030568.5) | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as COSV57616529; called by muse, mutect2, varscan2
- KHDRBS2 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV55499156, COSV99835833; called by muse, mutect2, varscan2
- KIAA0319 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100985560, COSV65501265; called by muse, mutect2, varscan2
- KIAA1549 | c.5680C>T p.P1894S (on ENST00000422774 / NM_001164665.2; = p.P1878S on NM_020910.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1387690328, COSV54309014; called by muse, mutect2, varscan2
- KIAA1549 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV54332217; called by muse, mutect2, varscan2
- KIAA1549 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs369822469; called by muse, mutect2, varscan2
- KIAA1614 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV62552046; called by muse, mutect2, varscan2
- KIF1A | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV57484488, COSV57486873; called by muse, mutect2, varscan2
- KIF21B | c.4150C>T p.R1384W (on ENST00000422435 / NM_001252100.2; = p.R1371W on NM_017596.4) | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148681629; called by muse, mutect2, varscan2
- KIF5A | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54054975; called by muse, mutect2, varscan2
- KIFAP3 | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.098); catalogued as COSV63038180; called by muse, mutect2, varscan2
- KIR3DL3 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.695); catalogued as rs113773573; called by muse, mutect2, varscan2
- KIRREL3 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs367848509; called by muse, mutect2, varscan2
- KIRREL3 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV69386876; called by muse, mutect2, varscan2
- KLHDC9 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV63510750; called by muse, mutect2, varscan2
- KLHL14 | c.1123T>C p.F375L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV63836146; called by muse, mutect2, varscan2
- KLHL20 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 74/162 reads (46%) | catalogued as rs749524628, COSV52943034, COSV52944636; called by muse, mutect2, varscan2
- KLHL4 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64147586; called by muse, mutect2, varscan2
- KLHL6 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV58070068; called by muse, mutect2, varscan2
- KLK11 | c.355C>T p.R119W (on ENST00000594768 / NM_144947.3; = p.R87W on NM_006853.3) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.932); catalogued as rs765819780; called by muse, mutect2, varscan2
- KLK8 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV51594516; called by muse, mutect2, varscan2
- KLK8 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as COSV51593280; called by muse, mutect2, varscan2
- KMO | c.1132T>A p.F378I | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as COSV59368018; called by muse, mutect2, varscan2
- KMT2A | c.6674C>T p.S2225F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV63284562; called by muse, mutect2, varscan2
- KMT2C | c.4940A>G p.E1647G | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV51516708; called by muse, mutect2, varscan2
- KMT2C | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 42/824 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV51460080, COSV51516738; called by muse, mutect2
- KNTC1 | c.3948A>T p.K1316N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV61085498; called by muse, mutect2
- KPRP | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.728); catalogued as COSV64221130; called by muse, mutect2, varscan2
- KRT2 | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs764751614, COSV59013063; called by muse, mutect2, varscan2
- KRT2 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1319518447, COSV59013222; called by muse, mutect2, varscan2
- KRT31 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs968220066; called by muse, mutect2, varscan2
- KRT6A | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.123); catalogued as COSV58108387; called by muse, mutect2, varscan2
- KRT7 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs1346579114, COSV59329796; called by muse, mutect2, varscan2
1,834 further variants in this file (973 protein-altering or splice-affecting, 791 silent, 70 other) are not listed here.
